Somatic mutation profile of tumor specimen MP2PRT-PAMXGS-TMP1-A (aliquot MP2PRT-PAMXGS-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAMXGS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,386 days).
Specimen MP2PRT-PAMXGS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 645aa1bd-0e73-4209-a2d5-ef2dee85a761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAMXGS-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAMXGS-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6647301f-00d3-429d-a312-1dfc60554f3e

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAJB11 | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 83/359 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as COSV54002638; called by muse, mutect2, varscan2
- FAM189A1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 115/438 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1310423284, COSV54268603; called by muse, mutect2, varscan2
- PCDHA7 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 177/785 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs782545562, COSV65344037; called by muse, mutect2, varscan2
- WTAP | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV61610446, COSV61610540; called by muse, mutect2
- KIAA1109 | c.9253C>G p.Q3085E | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PRUNE2 | c.1085C>G p.S362C | Missense Mutation (SNP) | VAF 132/418 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PTX3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 152/690 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROBO1 | c.2134C>G p.R712G | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A31 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.398); called by muse, mutect2
- WDR64 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 91/309 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF81 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CDV3 | c.489G>A p.A163= | Silent (SNP) | VAF 33/415 reads (8%) | catalogued as rs756324344; called by muse, mutect2
- CEACAM4 | c.90G>A p.P30= | Silent (SNP) | VAF 15/482 reads (3%) | catalogued as rs782380374, COSV55733249; called by muse, mutect2
- SOX11 | c.765C>T p.L255= | Silent (SNP) | VAF 58/687 reads (8%) | catalogued as rs751607049, COSV58987895; called by muse, mutect2
- SETD1A | c.-1G>C | 5'UTR (SNP) | VAF 26/364 reads (7%) | catalogued as COSV99353412; called by muse, mutect2
